Somatic mutation profile of tumor specimen 0DGBAD from CCDI case PBBTCY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 4.4 years (1,603 days).
Specimen 0DGBAD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38653e3a-a0bd-49e1-8a52-106d01ea8aaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGB92 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/689653dc-ce99-4f4b-9805-50912664e63c

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Frame Shift Ins 1, Splice Site 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL33 | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 148/318 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs776239903; called by muse, varscan2
- INF2 | c.2978G>A p.R993H | Missense Mutation (SNP) | VAF 320/680 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs531849769; called by muse, varscan2
- THEGL | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 64/600 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1265048967; called by muse, varscan2
- ARID1A | c.6009dup p.H2004Tfs*29 | Frame Shift Ins (INS) | VAF 176/468 reads (38%) | called by pindel, varscan2
- ARID1A | c.6041T>G p.L2014R | Missense Mutation (SNP) | VAF 204/558 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RTKN | c.427+1_427+3del p.X143_splice (on ENST00000272430 / NM_001015055.2; = p.X130_splice on NM_033046.2) | Splice Site (DEL) | VAF 232/523 reads (44%) | called by pindel, varscan2
- PLAGL1 | c.507G>A p.K169= | Silent (SNP) | VAF 200/361 reads (55%) | catalogued as rs765832081, COSV52788427; called by muse, varscan2
- RYR2 | c.12720G>A p.T4240= | Silent (SNP) | VAF 248/516 reads (48%) | catalogued as rs774851947, COSV100769352, COSV63665080; called by muse, varscan2
- CTRL | c.*93A>C | 3'UTR (SNP) | VAF 112/250 reads (45%) | catalogued as COSV99344414; called by muse, varscan2
- DDX41 | c.*307-20G>A | Intron (SNP) | VAF 290/597 reads (49%) | catalogued as rs763708504; called by muse, varscan2
